Somatic mutation profile of tumor specimen ALCH-B1VH-TTP1-A (aliquot ALCH-B1VH-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1VH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.4 years (24,617 days).
Specimen ALCH-B1VH-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e4dff2a-b096-45d2-b147-5a77c05e1838.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1VH-NB1-A (Blood Derived Normal), aliquot ALCH-B1VH-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4fd287a-6fb5-4bf2-b8e1-9242a4922a7a

The open-access MAF lists 160 somatic variants for this specimen: 106 protein-altering or splice-affecting, 40 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 40, Nonsense Mutation 12, Intron 8, Splice Site 5, Splice Region 2, 5'Flank 2, Frame Shift Del 1, 3'Flank 1, RNA 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN3 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100074151; called by muse, mutect2
- ADM | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 17/376 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV53403914; called by muse, mutect2
- AL669918.1 | c.2055G>C p.K685N | Missense Mutation (SNP) | VAF 28/572 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.04); catalogued as rs751362778; called by muse, mutect2
- CACNA1A | c.2421G>A p.W807* | Nonsense Mutation (SNP) | VAF 18/604 reads (3%) | catalogued as COSV64203761; called by muse, mutect2
- CAVIN2 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 12/318 reads (4%) | catalogued as rs1233082336; called by muse, mutect2
- CBFB | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51998344; called by muse, mutect2
- CCDC190 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.526); catalogued as COSV63363762, COSV99057712; called by muse, mutect2
- CDK12 | c.1639C>G p.Q547E | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); catalogued as COSV101420528; called by muse, mutect2
- CENPE | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54391389; called by muse, mutect2
- CXCL12 | c.158C>A p.P53Q | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV59107448; called by muse, mutect2
- DCAF6 | c.1849G>T p.E617* (on ENST00000312263 / NM_001349778.1; = p.E637* on NM_018442.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/400 reads (6%) | catalogued as COSV56583750; called by muse, mutect2
- DDIT4 | c.155C>G p.S52W | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100259100; called by muse, mutect2
- DNAAF5 | c.2389C>T p.H797Y | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs772896273; called by muse, mutect2
- EPYC | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs1400804202; called by muse, mutect2
- FBXL6 | c.1226-1G>A p.X409_splice | Splice Site (SNP) | VAF 9/172 reads (5%) | catalogued as COSV57351522; called by muse, mutect2
- FDX2 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.697); catalogued as rs1184197568, COSV53343885; called by muse, mutect2
- GRK2 | c.2050G>A p.G684S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1030574788, COSV57753057; called by muse, mutect2
- HLTF | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59501332; called by mutect2, varscan2
- LAMA4 | c.3998T>C p.V1333A (on ENST00000230538 / NM_001105206.3; = p.V1326A on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs781873319; called by muse, mutect2
- LIMK2 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.08); catalogued as COSV59182433; called by muse, mutect2
- MRC1 | c.226G>T p.G76* | Nonsense Mutation (SNP) | VAF 30/475 reads (6%) | catalogued as COSV100509749, COSV58890064; called by muse, mutect2
- MYH2 | c.3881C>T p.S1294L | Missense Mutation (SNP) | VAF 17/397 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as COSV55444973; called by muse, mutect2
- MYO3B | c.3709C>A p.L1237I | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); catalogued as COSV100512025; called by muse, mutect2
- NF1 | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 10/209 reads (5%) | catalogued as CM154906, COSV62226628; called by muse, mutect2
- NF1 | c.7102G>T p.E2368* (on ENST00000358273 / NM_001042492.3; = p.E2347* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 14/269 reads (5%) | catalogued as COSV62204812; called by muse, mutect2
- OR4A15 | c.440G>C p.W147S | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); catalogued as COSV59033869; called by muse, mutect2
- OR5P2 | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs772348115; called by muse, mutect2
- P3H2 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 16/429 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.175); catalogued as COSV100077161; called by muse, mutect2
- PCDHB12 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 39/668 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53392922; called by muse, mutect2
- PPP6R2 | c.2614G>C p.D872H (on ENST00000216061 / NM_001365836.1; = p.D838H on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.062); catalogued as COSV99323947; called by muse, mutect2
- PSG7 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV101343383; called by muse, mutect2, varscan2
- RASA1 | c.2644C>T p.Q882* | Nonsense Mutation (SNP) | VAF 16/304 reads (5%) | catalogued as COSV57193439; called by muse, mutect2
- SMAD2 | c.1217A>G p.Y406C | Missense Mutation (SNP) | VAF 24/303 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50997338; called by muse, mutect2
- SYNDIG1 | c.198G>C p.R66S | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs1003799591, COSV65234607; called by muse, mutect2
- TCTN2 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as rs1020961734, COSV57634171; called by muse, mutect2
- WNK1 | c.5650C>G p.H1884D (on ENST00000315939 / NM_018979.4; = p.H1636D on NM_014823.3) | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV60033737; called by muse, mutect2
- AACS | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.124); called by muse, mutect2
- ARMH4 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 23/336 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); called by muse, mutect2
- BCL11B | c.2589C>A p.F863L (on ENST00000357195 / NM_001282237.2; = p.F792L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/565 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- CACNG3 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 39/347 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAPZA1 | c.411_417del p.N138Sfs*77 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- CDK12 | c.1490C>A p.A497E | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2
- CELSR1 | c.2453C>T p.T818I | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); called by muse, mutect2
- CFH | c.2782G>T p.G928C | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CHD5 | c.2746C>A p.Q916K | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2
- CHD7 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.014); called by muse, mutect2
- CYFIP1 | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.066); called by muse, mutect2
- CYP11B2 | c.1056T>A p.S352R | Missense Mutation (SNP) | VAF 22/464 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2
- D2HGDH | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- DMBT1 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EGLN3 | c.478-1G>C p.X160_splice | Splice Site (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- ESRP2 | c.2095-2A>T p.X699_splice (on ENST00000565858 / NM_001365264.1; = p.X689_splice on NM_024939.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- FABP2 | c.243G>A p.G81= | Splice Region (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- FAM47A | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 14/325 reads (4%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.57); called by muse, mutect2
- FHOD3 | c.227T>A p.L76Q | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLNC | c.753G>A p.M251I | Missense Mutation (SNP) | VAF 30/586 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- GPR52 | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HACE1 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2
- HEXIM1 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); called by muse, mutect2
- JUP | c.1250A>G p.N417S | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIF22 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- KRTAP6-3 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 16/306 reads (5%) | called by muse, mutect2
- LY9 | c.1642G>T p.D548Y | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- MACF1 | c.8245G>T p.E2749* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- MAGEB6B | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 21/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAPK8IP2 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MECOM | c.951G>C p.L317F (on ENST00000468789 / NM_001105078.4; = p.L505F on NM_004991.4) | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, mutect2
- MED13 | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- MEP1B | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2
- MRPS23 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MS4A14 | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- MYH2 | c.2664A>T p.K888N | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- MYH4 | c.3208A>T p.T1070S | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- NHLH1 | c.252A>T p.E84D | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- OR10A3 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- OR10A3 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR10G4 | c.704G>T p.R235I | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- OR1S1 | c.516C>A p.H172Q | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OSBPL9 | c.227C>A p.T76N | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PACSIN1 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PPAN-P2RY11 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2
- PPP1R8 | c.609C>G p.F203L | Missense Mutation (SNP) | VAF 19/294 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PRR35 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.014); called by muse, mutect2
- PYROXD2 | c.992C>A p.T331K | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- RAB40C | c.143-3C>G | Splice Region (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- RBM5 | c.18-1G>A p.X6_splice | Splice Site (SNP) | VAF 7/169 reads (4%) | called by muse, mutect2
- RELN | c.5304C>A p.C1768* | Nonsense Mutation (SNP) | VAF 25/494 reads (5%) | called by muse, mutect2
- RYR2 | c.9729C>A p.C3243* | Nonsense Mutation (SNP) | VAF 16/326 reads (5%) | called by muse, mutect2
- SEC16A | c.6824C>T p.S2275F | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2
- SLITRK3 | c.998C>G p.P333R | Missense Mutation (SNP) | VAF 43/424 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.77); called by muse, mutect2
- SOCS6 | c.1506C>G p.Y502* | Nonsense Mutation (SNP) | VAF 13/394 reads (3%) | called by muse, mutect2
- SOGA1 | c.3187G>C p.E1063Q | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- SPEF2 | c.2489G>A p.R830K | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2
- SUN1 | c.1811C>T p.S604F (on ENST00000405266 / NM_001367651.1; = p.S484F on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); called by muse, mutect2
- TEX15 | c.3122G>T p.W1041L (on ENST00000256246; = p.W1424L on NM_001350162.2) | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TF | c.1298-1G>C p.X433_splice | Splice Site (SNP) | VAF 13/145 reads (9%) | called by muse, mutect2
- TRIM39 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.692); called by muse, mutect2
- UNC13C | c.3521G>T p.R1174I | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- UTS2R | c.239T>G p.L80R | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- WNK3 | c.1193A>C p.D398A | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2
- ZNF605 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF606 | c.2024C>T p.T675I | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF804B | c.1420G>T p.G474C | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZSCAN1 | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.024); called by muse, mutect2
- ZSWIM2 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2
- ZSWIM5 | c.3166G>C p.E1056Q | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); called by muse, mutect2
- ACKR1 | c.393G>T p.L131= | Silent (SNP) | VAF 7/146 reads (5%) | catalogued as COSV100929539, COSV63671654; called by muse, mutect2
- AGTPBP1 | c.1255C>T p.L419= (on ENST00000357081 / NM_001330701.2; = p.L379= on NM_015239.2) | Silent (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- AKNAD1 | c.1488A>G p.P496= | Silent (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- ANO7 | c.1929G>A p.E643= (on ENST00000274979; = p.E589= on NM_001370694.2) | Silent (SNP) | VAF 20/254 reads (8%) | catalogued as rs1473163623; called by muse, mutect2
- CNDP1 | c.366C>T p.P122= | Silent (SNP) | VAF 9/287 reads (3%) | called by muse, mutect2
- DRD5 | c.282C>T p.V94= | Silent (SNP) | VAF 14/402 reads (3%) | catalogued as rs1407865457; called by muse, mutect2
- DUSP2 | c.264C>T p.A88= | Silent (SNP) | VAF 6/105 reads (6%) | called by muse, mutect2
- EIF3K | c.45C>G p.L15= | Silent (SNP) | VAF 12/212 reads (6%) | called by muse, mutect2
- EXOC6 | c.22C>T p.L8= | Silent (SNP) | VAF 19/354 reads (5%) | called by muse, mutect2
- FAM185A | c.243C>G p.L81= | Silent (SNP) | VAF 7/164 reads (4%) | called by muse, mutect2
- FAT3 | c.8208G>A p.Q2736= | Silent (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
- GMPS | c.807C>T p.H269= | Silent (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- GRIK4 | c.2850C>T p.T950= | Silent (SNP) | VAF 9/194 reads (5%) | called by muse, mutect2
- HECW1 | c.3147C>A p.P1049= | Silent (SNP) | VAF 7/190 reads (4%) | catalogued as rs1380129563; called by muse, mutect2
- HECW1 | c.3148C>A p.R1050= | Silent (SNP) | VAF 7/194 reads (4%) | called by muse, mutect2
- HS3ST3A1 | c.666G>T p.T222= | Silent (SNP) | VAF 14/308 reads (5%) | catalogued as COSV52372561; called by muse, mutect2
- KCNG3 | c.255C>T p.F85= | Silent (SNP) | VAF 14/248 reads (6%) | catalogued as rs1285138887, COSV60148332; called by muse, mutect2
- LARP1 | c.1614A>G p.L538= (on ENST00000518297 / NM_033551.3; = p.L461= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- MED12L | c.3423C>A p.A1141= | Silent (SNP) | VAF 57/490 reads (12%) | called by muse, mutect2, varscan2
- MRPL15 | c.498C>T p.A166= | Silent (SNP) | VAF 11/176 reads (6%) | called by muse, mutect2
- MRPL16 | c.591G>A p.K197= | Silent (SNP) | VAF 17/234 reads (7%) | called by muse, mutect2
- MUC17 | c.4812G>T p.V1604= | Silent (SNP) | VAF 7/135 reads (5%) | called by muse, mutect2
- MYH8 | c.3679C>T p.L1227= | Silent (SNP) | VAF 16/392 reads (4%) | called by muse, mutect2
- OR2T35 | c.900T>A p.A300= | Silent (SNP) | VAF 10/275 reads (4%) | catalogued as COSV100442304; called by muse, mutect2
- OR9Q2 | c.681G>A p.Q227= | Silent (SNP) | VAF 14/237 reads (6%) | called by muse, mutect2
- OTOF | c.3882C>G p.V1294= (on ENST00000272371 / NM_194248.3; = p.V527= on NM_004802.4) | Silent (SNP) | VAF 14/412 reads (3%) | called by muse, mutect2
- OTOG | c.1383C>T p.L461= | Silent (SNP) | VAF 11/177 reads (6%) | catalogued as rs866138206; called by muse, mutect2
- PCDHGB7 | c.693G>T p.L231= | Silent (SNP) | VAF 23/420 reads (5%) | called by muse, mutect2
- PCNX1 | c.5778C>T p.I1926= | Silent (SNP) | VAF 14/304 reads (5%) | called by muse, mutect2
- PIP4K2C | c.72C>T p.F24= | Silent (SNP) | VAF 14/198 reads (7%) | catalogued as COSV61605594, COSV61606167; called by muse, mutect2
- PLPP7 | c.546C>G p.L182= | Silent (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- POU4F3 | c.915G>C p.A305= | Silent (SNP) | VAF 32/562 reads (6%) | called by muse, mutect2
- PRAMEF14 | c.840C>T p.F280= | Silent (SNP) | VAF 22/376 reads (6%) | called by muse, mutect2
- PTK2B | c.2052G>A p.Q684= | Silent (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- PYROXD2 | c.993A>C p.T331= | Silent (SNP) | VAF 16/279 reads (6%) | catalogued as COSV65328687; called by muse, mutect2
- RNF111 | c.663C>G p.S221= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- SERINC2 | c.72C>A p.I24= (on ENST00000373709 / NM_178865.5; = p.I28= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/214 reads (8%) | called by muse, mutect2
- SLC7A11 | c.1365C>T p.V455= | Silent (SNP) | VAF 16/246 reads (7%) | called by muse, mutect2
- TTN | c.38586C>T p.L12862= (on ENST00000591111; = p.L5438= on NM_003319.4) | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV59903161; called by muse, mutect2, varscan2
- VSTM5 | c.63C>T p.L21= | Silent (SNP) | VAF 28/319 reads (9%) | catalogued as rs771292885, COSV101336282; called by muse, mutect2
- ABCA2 | c.251-367C>T | Intron (SNP) | VAF 16/243 reads (7%) | called by muse, mutect2
- ATP5F1B | c.310+105C>T | Intron (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- BICDL2 | chr16:3036295 C>A | 5'Flank (SNP) | VAF 9/81 reads (11%) | catalogued as rs1185849082; called by muse, mutect2, varscan2
- C11orf52 | chr11:111929874 G>T | 3'Flank (SNP) | VAF 16/265 reads (6%) | called by muse, mutect2
- DST | c.4297-4861G>A | Intron (SNP) | VAF 5/62 reads (8%) | catalogued as rs992513075; called by muse, mutect2
- MIR382 | n.27G>T | RNA (SNP) | VAF 10/312 reads (3%) | called by muse, mutect2
- NFKBID | chr19:35902197 C>T | 5'Flank (SNP) | VAF 10/183 reads (5%) | called by muse, mutect2
- PAXIP1 | c.325-2744C>T | Intron (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
- PNPLA6 | c.-38C>G | 5'UTR (SNP) | VAF 11/200 reads (6%) | called by muse, mutect2
- PPAN | c.292-77G>A | Intron (SNP) | VAF 7/136 reads (5%) | catalogued as rs1324880117; called by muse, mutect2
- SPHK2 | c.40-122C>G | Intron (SNP) | VAF 22/462 reads (5%) | called by muse, mutect2
- SUMO3 | c.222+500G>C | Intron (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- TALDO1 | c.461+45C>G | Intron (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- WFDC3 | c.*24C>G | 3'UTR (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
